Gene-level copy-number profile of tumor specimen C3L-00416-02 from CPTAC case C3L-00416, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 62.0 years (22,653 days).
Specimen C3L-00416-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b81f5808-c06c-4d3f-872d-387d83833402.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00416-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/311f86dd-52de-4ea0-9563-0ce9cdf30938

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,399; copy number 1: 7,208; copy number 2: 46,056; copy number 3: 2,678; copy number 4: 1,566; copy number 5: 5.

Homozygous deletions (total copy number 0; autosomes only): 1,398 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–86,496,996, 1,314 genes (broad region; genes not listed).
- chr14:22,185,562–22,552,156, 84 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,372. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
